TCGA case TCGA-CV-7235 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2fbafcc5-896c-4e50-8956-a61540fc89be

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C04.9; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 67.9 years (24,800 days); Year of diagnosis: 2007; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,347 days (6.4 years).
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 64; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 43 days; Days to treatment end: 81 days; Treatment dose: 20 Gy; Treatment outcome: Complete Response; Number of fractions: 10; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 46 days; Days to treatment end: 81 days; Treatment dose: 40 Gy; Treatment outcome: Complete Response; Number of fractions: 20; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,724 days (4.7 years); Disease response: Tumor Free.
- Days to follow up: 2,347 days (6.4 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 97.5; Tobacco smoking onset year: 1952; Tobacco smoking quit year: 1991.
- Alcohol history: Yes; Alcohol drinks per day: 4; Alcohol days per week: 7.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-7235-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.2; Shortest dimension: 0.5.
  Slide TCGA-CV-7235-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40.
  Slide TCGA-CV-7235-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40.
- Sample TCGA-CV-7235-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-7235-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-CV-7235-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Positive; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 3; Alcohol consumption frequency: 7.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,347 days; disease-specific survival: no event (censored), 2,347 days; disease-free interval: no event (censored), 2,347 days; progression-free interval: no event (censored), 2,347 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CV-7235-01A-11D-2010-01): tumor purity 0.54, ploidy 2.89, whole-genome doublings 1.
